TCGA case TCGA-YL-A9WL — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: PROCURE Biobank. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cfcf057a-00fe-4603-a720-586712b75803

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 59.2 years (21,626 days); Year of diagnosis: 2011; Method of diagnosis: Core Biopsy; AJCC clinical T: T2a; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N0; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 5; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 15; Tumor level prostate: Apex / Middle / Base; Zone of origin prostate: Overlapping/multiple zones.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Days to treatment start: 271 days; Days to treatment end: 349 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 370 days (1.0 years); Days to treatment end: 417 days (1.1 years); Treatment dose: 66 Gy; Treatment outcome: Complete Response; Number of fractions: 22; Treatment anatomic sites: Locoregional Site.

Follow-up (3 entries)
- Day 28 (initial diagnosis): Days to imaging: 28 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 39 (initial diagnosis): Days to imaging: 39 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.
- Day 740 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 740 days (2.0 years).

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 6.4 ng/mL (day 740).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YL-A9WL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,300 mg.
  Slide TCGA-YL-A9WL-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-YL-A9WL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YL-A9WL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: No; Lymph nodes examined: Yes; Treatment outcome first course: Complete Remission/Response; Biochemical recurrence indicator: Yes; New tumor event diagnosis indicator: Yes.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Stage record, Psa: PSA most recent results: 6.4.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 5; Gleason pattern tertiary: 3.
- New tumor event: New tumor event type: Biochemical evidence of disease; Progression after hormone treatment: Yes; Progression after hormone treatment type: Biochemical Recurrence.
- Drug treatment: Pharmaceutical therapy drug name: Lupron.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event type: Biochemical evidence of disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 740 days; disease-specific survival: no event (censored), 740 days; disease-free interval: event (new tumor event after initially disease-free), 740 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 740 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YL-A9WL-01A-11D-A41J-01): tumor purity 0.94, ploidy 1.87, whole-genome doublings 0.
